Somatic mutation profile of tumor specimen C3L-00819-01 (aliquot CPT0064090006) from CPTAC case C3L-00819, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 74.2 years (27,104 days).
Specimen C3L-00819-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b00b863-9858-4fa9-93bb-c509b6e709d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00819-31 (Blood Derived Normal), aliquot CPT0065380002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e99921c9-414f-4cd5-8f5f-b0691a2dd0f7

The open-access MAF lists 60 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 13, Nonsense Mutation 2, Intron 2, 5'Flank 2, Splice Site 2, RNA 2, Frame Shift Ins 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 15/104 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRA1 | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 74/487 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs756879823; called by muse, mutect2, varscan2
- BLID | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.135); catalogued as rs749390802; called by muse, mutect2, varscan2
- C8orf48 | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV52047574; called by mutect2, varscan2
- CSMD1 | c.3230G>A p.R1077H (on ENST00000520002; = p.R1076H on NM_033225.6) | Missense Mutation (SNP) | VAF 35/310 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748686121, COSV59302829; called by muse, mutect2, varscan2
- DCST1 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 67/563 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750570779; called by muse, mutect2, varscan2
- DNAJC16 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs200056658, COSV61600805; called by muse, mutect2, varscan2
- EPHA7 | c.2256G>C p.M752I | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as COSV65177684, COSV65183225, COSV65185967; called by muse, mutect2
- GOLGB1 | c.9697C>T p.R3233W | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745651336, COSV58859217; called by muse, mutect2, varscan2
- MAGEB17 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as rs763866721, COSV61556951; called by muse, mutect2, varscan2
- MDN1 | c.12209C>T p.T4070M | Missense Mutation (SNP) | VAF 43/436 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs1433289462, COSV65534599; called by muse, mutect2
- NIBAN2 | c.1462C>T p.R488W | Missense Mutation (SNP) | VAF 74/399 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs772145640, COSV55941898; called by muse, mutect2, varscan2
- PLVAP | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 76/606 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs772839272, COSV53087213; called by muse, mutect2, varscan2
- PTGIS | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 95/817 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.024); catalogued as rs561823415, COSV54840430; called by muse, mutect2, varscan2
- SCN3A | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 34/256 reads (13%) | catalogued as rs1288869563, COSV51800546, COSV51814482; called by muse, mutect2, varscan2
- SHROOM2 | c.2803G>A p.E935K | Missense Mutation (SNP) | VAF 64/282 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.41); catalogued as rs1002335210; called by muse, mutect2, varscan2
- SIGLEC14 | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 44/437 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as rs778439662; called by muse, mutect2, varscan2
- SPINT2 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 92/754 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755052415; called by muse, mutect2, varscan2
- SYN3 | c.1465C>T p.R489W | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs151051257; called by muse, mutect2, varscan2
- TTR | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 160/1435 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.495); catalogued as rs148538950; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWA5B2 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs765197607; called by muse, mutect2, varscan2
- ZNF454 | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.282); catalogued as COSV60769341; called by muse, mutect2, varscan2
- ZNF471 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs578040016; called by muse, mutect2, varscan2
- CDK20 | c.62C>G p.A21G | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CHADL | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM216B | c.29A>G p.K10R | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.043); called by muse, mutect2
- IGKV1D-43 | c.245C>G p.S82* | Nonsense Mutation (SNP) | VAF 18/378 reads (5%) | called by muse, mutect2
- KLF5 | c.620del p.F207Sfs*26 | Frame Shift Del (DEL) | VAF 27/241 reads (11%) | called by mutect2, pindel, varscan2
- MIER1 | c.5A>G p.D2G | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MSH5 | c.147+2T>G p.X49_splice | Splice Site (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- MYH1 | c.2509T>A p.Y837N | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.181); called by muse, mutect2
- OTX1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 51/337 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDCD2 | c.777_778insCC p.R260Pfs*40 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by mutect2, pindel
- SCUBE3 | c.2268C>G p.N756K | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SFTPA1 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 53/424 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBAP2L | c.2147C>T p.S716F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- USP28 | c.136-3_136-2del p.X46_splice | Splice Site (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- WSB1 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF469 | c.7525G>A p.E2509K (on ENST00000437464; = p.E2537K on NM_001367624.2) | Missense Mutation (SNP) | VAF 82/632 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- ZZEF1 | c.7007G>C p.S2336T | Missense Mutation (SNP) | VAF 75/637 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AGBL4 | c.1356G>A p.P452= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as rs927622923; called by muse, mutect2, varscan2
- BEND3 | c.2031C>T p.P677= | Silent (SNP) | VAF 47/362 reads (13%) | catalogued as rs781978327; called by muse, mutect2, varscan2
- CCAR2 | c.2580G>A p.E860= | Silent (SNP) | VAF 58/524 reads (11%) | catalogued as rs1296096634; called by muse, mutect2, varscan2
- CXCR3 | c.984G>A p.R328= | Silent (SNP) | VAF 28/181 reads (15%) | catalogued as rs747616337; called by muse, mutect2, varscan2
- GOLGB1 | c.3735C>T p.D1245= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as rs759460081, COSV61464925; called by mutect2, varscan2
- NLRP6 | c.1272C>G p.T424= | Silent (SNP) | VAF 36/480 reads (8%) | called by muse, mutect2
- NYNRIN | c.5271G>A p.P1757= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs368739121; called by mutect2, varscan2
- OR1A2 | c.609C>T p.V203= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs150553361; called by muse, mutect2, varscan2
- PSD2 | c.1086C>T p.D362= | Silent (SNP) | VAF 33/289 reads (11%) | catalogued as rs747518596, COSV51199034; called by muse, mutect2, varscan2
- RASAL2 | c.2739G>A p.Q913= | Silent (SNP) | VAF 34/442 reads (8%) | called by muse, mutect2
- SLC29A2 | c.1050C>T p.Y350= | Silent (SNP) | VAF 65/599 reads (11%) | called by muse, mutect2, varscan2
- SPHKAP | c.3327G>A p.P1109= | Silent (SNP) | VAF 20/177 reads (11%) | catalogued as rs199683355; called by muse, mutect2, varscan2
- VAX1 | c.159G>A p.A53= | Silent (SNP) | VAF 81/794 reads (10%) | called by muse, mutect2, varscan2
- FAM21FP | n.313C>T | RNA (SNP) | VAF 42/528 reads (8%) | catalogued as rs1372039502; called by muse, mutect2
- HOXA2 | c.392-31G>A | Intron (SNP) | VAF 105/838 reads (13%) | called by muse, mutect2, varscan2
- KIF13B | chr8:29263087 A>C | 5'Flank (SNP) | VAF 74/571 reads (13%) | called by muse, mutect2, varscan2
- MYL5 | chr4:673849 A>T | 5'Flank (SNP) | VAF 95/690 reads (14%) | called by muse, mutect2, varscan2
- PIPSL | n.796C>T | RNA (SNP) | VAF 24/232 reads (10%) | called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088363 G>A | 3'Flank (SNP) | VAF 16/139 reads (12%) | catalogued as rs944114015; called by muse, mutect2, varscan2
- ZCWPW2 | c.658-2965dup | Intron (INS) | VAF 3/30 reads (10%) | called by mutect2, pindel
